Somatic mutation profile of tumor specimen TCGA-96-7545-01A (aliquot TCGA-96-7545-01A-21D-2042-08) from TCGA case TCGA-96-7545, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 73.2 years (26,729 days).
Specimen TCGA-96-7545-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75f0497d-3452-4d3d-ac71-fd3d281f50a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-96-7545-10A (Blood Derived Normal), aliquot TCGA-96-7545-10A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/916ec425-065c-4a3d-9368-73b2abed0439

The open-access MAF lists 135 somatic variants for this specimen: 100 protein-altering or splice-affecting, 31 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 31, Nonsense Mutation 7, Frame Shift Del 3, Intron 2, Splice Site 2, Splice Region 1, In Frame Del 1, Frame Shift Ins 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11552822, CM085316, CM990358, COSV58683210, COSV58683289, COSV58686242, COSV58694349; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 11/45 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960096, COSV67960161, COSV67961129; called by muse, mutect2, varscan2
- TP53 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.1064T>A p.V355E | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV100588975; called by muse, mutect2, varscan2
- AATF | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.226); catalogued as rs761448475; called by muse, mutect2, varscan2
- ABCC12 | c.99C>G p.I33M | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV100253178; called by muse, mutect2, varscan2
- ADAM15 | c.1697G>T p.G566V | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99665305; called by muse, mutect2
- ADAMTS20 | c.2966G>A p.R989Q | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767096383, COSV67138630; called by muse, mutect2, varscan2
- APOB | c.10988G>A p.G3663E | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs267599179, COSV51940144; called by muse, mutect2, varscan2
- ATP2B1 | c.1019A>T p.E340V | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.311); catalogued as COSV99666101; called by muse, mutect2, varscan2
- BRINP1 | c.1862G>T p.S621I | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99776801; called by muse, mutect2, varscan2
- C5 | c.4829A>T p.E1610V | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV99798629; called by muse, mutect2, varscan2
- CNTN6 | c.1162G>T p.A388S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs768433383, COSV63192862; called by muse, mutect2, varscan2
- CREB3L4 | c.826C>G p.Q276E | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99665826; called by muse, mutect2, varscan2
- CREBBP | c.3979A>T p.K1327* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV52128071; called by muse, mutect2, varscan2
- CSRP1 | c.67G>A p.V23I | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.043); catalogued as rs1388656859, COSV100384574; called by muse, mutect2, varscan2
- CYP1B1 | c.1048C>G p.P350A | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV99308192; called by muse, mutect2
- CYP26B1 | c.723G>T p.Q241H | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV50012831, COSV99134944; called by muse, mutect2, varscan2
- DNAH7 | c.6020C>G p.S2007* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as COSV100417324; called by muse, mutect2, varscan2
- DPP6 | c.2023G>A p.E675K (on ENST00000377770 / NM_001364500.2; = p.E613K on NM_001936.5) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as rs377194563; called by muse, mutect2, varscan2
- EPG5 | c.3037G>A p.V1013M | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99958031; called by muse, mutect2, varscan2
- EPHA3 | c.734G>T p.S245I | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100348356; called by muse, mutect2, varscan2
- EPHA3 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100348358; called by muse, mutect2, varscan2
- ESYT1 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV99920251; called by muse, mutect2, varscan2
- FMN2 | c.2278G>C p.V760L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.023); catalogued as rs1304119504, COSV100146991; called by muse, mutect2, varscan2
- FOXG1 | c.1219G>A p.V407I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.444); catalogued as rs1287203413, COSV57396534; called by muse, mutect2, varscan2
- FUT6 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV99744933; called by muse, mutect2, varscan2
- FUT9 | c.449A>G p.H150R | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.326); catalogued as COSV100134268; called by muse, mutect2
- GALNT13 | c.95A>G p.N32S | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV101224153, COSV67224767; called by muse, mutect2, varscan2
- GALNT18 | c.1712G>A p.C571Y | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99925766; called by muse, mutect2, varscan2
- GGT1 | c.1076C>A p.S359Y | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV99959295; called by muse, varscan2
- GRIN2A | c.2563G>T p.D855Y | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100410936, COSV58024134, COSV58059538; called by muse, mutect2
- HECTD4 | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101108351; called by muse, mutect2, varscan2
- HOXA3 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100415674; called by mutect2, varscan2
- HRNR | c.1951C>A p.Q651K | Missense Mutation (SNP) | VAF 49/327 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100913897; called by muse, mutect2, varscan2
- IGKV1D-17 | c.62G>C p.R21T | Missense Mutation (SNP) | VAF 42/289 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.554); catalogued as rs768991692; called by muse, mutect2, varscan2
- JAKMIP1 | c.251T>A p.L84Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV99290669, COSV99290704; called by muse, mutect2, varscan2
- KCNC2 | c.1728C>A p.F576L | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.39); catalogued as COSV100129786, COSV54364250; called by muse, mutect2, varscan2
- KCNC4 | c.1042G>A p.V348M | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.931); catalogued as COSV100873693, COSV63924947; called by muse, mutect2, varscan2
- KRT84 | c.931T>A p.S311T | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.95); catalogued as COSV99231026; called by muse, mutect2, varscan2
- LAMA2 | c.7333C>T p.Q2445* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV101370808; called by muse, mutect2
- LONRF2 | c.1126C>G p.L376V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.131); catalogued as COSV101111048; called by muse, mutect2, varscan2
- LRRTM4 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV101297723, COSV69142957; called by muse, mutect2, varscan2
- MAN1A1 | c.1568C>G p.A523G | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV100870741; called by muse, mutect2
- MDGA2 | c.2176T>C p.W726R (on ENST00000399232 / NM_001113498.2; = p.W428R on NM_182830.4) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100638307; called by muse, mutect2, varscan2
- MMS22L | c.2023G>C p.V675L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99247649; called by muse, mutect2
- MROH2B | c.278A>G p.Y93C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV101270900; called by muse, mutect2, varscan2
- MYLK | c.1051A>G p.R351G | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV100659565; called by muse, mutect2, varscan2
- MYO1A | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766408233, COSV55653738; called by muse, mutect2, varscan2
- NCOA7 | c.256A>T p.R86* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV99997612; called by muse, mutect2
- NKAIN3 | c.410G>A p.G137D | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.274); catalogued as COSV100136401, COSV60680298; called by muse, mutect2, varscan2
- NME7 | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100891148, COSV63168931; called by muse, mutect2, varscan2
- NPAS3 | c.2543C>T p.A848V (on ENST00000356141 / NM_001164749.2; = p.A816V on NM_022123.3) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV60864542; called by muse, mutect2, varscan2
- OPHN1 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.34); catalogued as COSV100830248, COSV100830744; called by muse, mutect2, varscan2
- OR5D14 | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs138241507, COSV59457772; called by muse, mutect2, varscan2
- OR5F1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765027940, COSV53546678; called by muse, mutect2, varscan2
- PARD6G | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100783470; called by muse, mutect2
- PGM2L1 | c.1103G>A p.C368Y | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.516); catalogued as COSV99995179; called by muse, mutect2, varscan2
- PGM3 | c.124A>G p.M42V | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.388); catalogued as rs758805908, COSV99392550; called by muse, mutect2, varscan2
- PHOX2B | c.813A>C p.Q271H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99891699; called by muse, mutect2
- PPP1R9A | c.176A>G p.Y59C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99198558; called by muse, mutect2, varscan2
- PTPN9 | c.1067A>T p.D356V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100144540; called by muse, mutect2, varscan2
- RASAL3 | c.2963C>A p.S988Y | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.06); catalogued as COSV99653728; called by muse, mutect2, varscan2
- RLBP1 | c.678G>A p.M226I | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.563); catalogued as rs1398137944, COSV51527716, COSV99175394; called by muse, mutect2, varscan2
- RPS6KB1 | c.961A>G p.R321G | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99847731; called by muse, mutect2, varscan2
- SASH1 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as rs1169171191, COSV100821419; called by muse, varscan2
- SCN8A | c.2815G>A p.E939K | Missense Mutation (SNP) | VAF 52/308 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100634212, COSV61976774; called by muse, mutect2, varscan2
- SF3B1 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV100135684; called by muse, mutect2, varscan2
- SGCZ | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101171516, COSV65996376; called by muse, mutect2, varscan2
- SLC35F4 | c.875T>A p.L292Q (on ENST00000339762 / NM_001352015.2; = p.L256Q on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100334193; called by muse, mutect2, varscan2
- SLC6A3 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.866); catalogued as rs760467074, COSV99548802; called by muse, mutect2, varscan2
- SLCO5A1 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.511); catalogued as rs767922149, COSV52653280, COSV99480941; called by muse, mutect2, varscan2
- SLITRK3 | c.1311G>T p.L437F | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99580071; called by muse, mutect2
- SLITRK3 | c.1055A>G p.Y352C | Missense Mutation (SNP) | VAF 138/496 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.935); catalogued as COSV99580080; called by muse, mutect2, varscan2
- SLITRK6 | c.2309G>A p.G770E | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV101233290; called by muse, mutect2, varscan2
- SRGAP1 | c.2927T>A p.L976Q | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV100755094; called by muse, mutect2, varscan2
- SRRM2 | c.4566del p.V1523Lfs*25 | Frame Shift Del (DEL) | VAF 13/129 reads (10%) | catalogued as COSV100070762; called by mutect2, pindel, varscan2
- SUN5 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.412); catalogued as rs577770806, COSV50066399; called by muse, mutect2, varscan2
- TAAR5 | c.737A>C p.H246P | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs762632022, COSV99236990; called by muse, mutect2, varscan2
- TLCD1 | c.279G>A p.G93= | Splice Region (SNP) | VAF 8/86 reads (9%) | catalogued as COSV99262244; called by muse, mutect2
- TMC6 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs752560268, COSV100130362; called by muse, mutect2, varscan2
- TMEM132D | c.578T>C p.V193A | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV101399444; called by muse, mutect2, varscan2
- TRIM43 | c.395C>A p.A132E | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99720094; called by muse, mutect2, varscan2
- TRRAP | c.6808+1G>A p.X2270_splice (on ENST00000359863 / NM_001244580.1; = p.X2252_splice on NM_003496.3) | Splice Site (SNP) | VAF 36/146 reads (25%) | catalogued as COSV100722898; called by muse, mutect2, varscan2
- TSPAN5 | c.188G>T p.W63L | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.029); catalogued as COSV99995823; called by muse, mutect2, varscan2
- TUBA8 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.551); catalogued as COSV100283189, COSV57814210; called by muse, mutect2, varscan2
- ZFHX4 | c.7840C>A p.P2614T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99267064; called by muse, mutect2
- ZNF165 | c.254A>C p.K85T | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101056056; called by muse, mutect2, varscan2
- ZNF208 | c.2803C>T p.H935Y | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV68111998; called by muse, mutect2, varscan2
- ZNF568 | c.519A>C p.Q173H | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100451427; called by muse, mutect2, varscan2
- ZNF782 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as COSV100001630, COSV56654489; called by muse, mutect2, varscan2
- DNAH5 | c.9938del p.G3313Afs*25 | Frame Shift Del (DEL) | VAF 19/170 reads (11%) | called by mutect2, pindel, varscan2
- DNAJC11 | c.100_103del p.Y34Gfs*99 | Frame Shift Del (DEL) | VAF 19/87 reads (22%) | called by mutect2, pindel, varscan2
- GDF10 | c.776T>C p.V259A | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- LBP | c.84dup p.G29Rfs*25 | Frame Shift Ins (INS) | VAF 11/72 reads (15%) | called by mutect2, pindel, varscan2
- MRC1 | c.563C>A p.S188* | Nonsense Mutation (SNP) | VAF 39/246 reads (16%) | called by muse, mutect2, varscan2
- NBPF9 | c.74G>T p.R25L | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- PCIF1 | c.829C>T p.R277* | Nonsense Mutation (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- SBF1 | c.2644-6_2645del p.X882_splice | Splice Site (DEL) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- TMUB2 | c.637_639del p.L213del (on ENST00000538716 / NM_001353177.2; = p.L193del on NM_024107.3 and 5 other RefSeq transcripts) | In Frame Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel, varscan2
- ANXA11 | c.1263C>T p.G421= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV99627498; called by muse, mutect2, varscan2
- APBB2 | c.792G>T p.T264= | Silent (SNP) | VAF 58/272 reads (21%) | catalogued as COSV99924032; called by muse, mutect2, varscan2
- CATSPERE | c.1462C>T p.L488= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV100835253; called by muse, mutect2, varscan2
- CD163 | c.507T>C p.S169= | Silent (SNP) | VAF 43/295 reads (15%) | catalogued as COSV100776100; called by muse, mutect2, varscan2
- CILP2 | c.2991G>T p.G997= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV99365149; called by muse, mutect2, varscan2
- ETNPPL | c.819C>A p.I273= | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as rs750998495, COSV56595111; called by muse, mutect2, varscan2
- GPAT2 | c.1164C>T p.I388= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs761273723, COSV64003311; called by muse, mutect2, varscan2
- GPR12 | c.150C>A p.V50= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs137999425, COSV67344398; called by muse, mutect2, varscan2
- HDDC2 | c.264A>T p.A88= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV100600283; called by muse, mutect2, varscan2
- LGR5 | c.936G>T p.L312= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as COSV57003040, COSV99878423; called by muse, mutect2, varscan2
- LHX9 | c.195G>A p.P65= | Silent (SNP) | VAF 30/168 reads (18%) | catalogued as rs754550934, COSV100436061; called by mutect2, varscan2
- MUC16 | c.6237G>C p.G2079= | Silent (SNP) | VAF 37/163 reads (23%) | catalogued as COSV101201430; called by muse, mutect2, varscan2
- NAT1 | c.543A>G p.L181= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as COSV100306573; called by muse, mutect2, varscan2
- NAV3 | c.1320C>A p.P440= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as rs766596287, COSV57103711; called by muse, mutect2, varscan2
- NECTIN3 | c.699A>G p.L233= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100162719; called by muse, mutect2, varscan2
- NPAP1 | c.525G>A p.E175= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs768064836, COSV100276126; called by muse, mutect2, varscan2
- OR5T2 | c.84T>C p.C28= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs1404935815, COSV100507063; called by muse, mutect2
- PBXIP1 | c.1584G>T p.G528= | Silent (SNP) | VAF 35/232 reads (15%) | catalogued as COSV100870124, COSV63777036; called by muse, mutect2, varscan2
- PCDHB9 | c.1851G>A p.V617= | Silent (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- PCDHGB3 | c.69T>C p.S23= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs763997500, COSV53907438; called by muse, mutect2, varscan2
- RITA1 | c.19C>T p.L7= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100014167; called by muse, mutect2, varscan2
- SHANK2 | c.2733C>G p.S911= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99575910; called by muse, mutect2, varscan2
- SLC17A3 | c.825G>T p.L275= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100399392; called by muse, mutect2, varscan2
- SLC9A3 | c.1011C>T p.Y337= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV99376609; called by muse, mutect2
- TBC1D23 | c.1665G>A p.G555= (on ENST00000394144 / NM_001199198.3; = p.G540= on NM_018309.5) | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100792739; called by muse, mutect2, varscan2
- TCHHL1 | c.156T>C p.A52= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100916605; called by muse, mutect2
- TMEM131L | c.969A>G p.S323= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV99548092; called by muse, mutect2, varscan2
- TTN | c.22239A>G p.P7413= (on ENST00000591111; = p.P6486= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100628145; called by muse, mutect2, varscan2
- TYW1 | c.1293G>A p.V431= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV100659066; called by muse, mutect2, varscan2
- ZNF165 | c.1338C>T p.H446= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs370302417; called by muse, mutect2, varscan2
- ZNF229 | c.2208C>T p.G736= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs777593082, COSV52160763; called by muse, mutect2, varscan2
- ACYP1 | c.84+1764T>A | Intron (SNP) | VAF 4/27 reads (15%) | catalogued as COSV99465214; called by muse, mutect2
- ANKRD54 | c.-66G>T | 5'UTR (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99316564; called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827954 A>G | 3'Flank (SNP) | VAF 11/30 reads (37%) | catalogued as COSV100158170; called by muse, mutect2, varscan2
- TTN | c.10360+1156A>G | Intron (SNP) | VAF 56/273 reads (21%) | catalogued as rs762345462, COSV60453871; called by muse, mutect2, varscan2
